Gene-level copy-number profile of tumor specimen TCGA-DX-AB3B-01A from TCGA case TCGA-DX-AB3B, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 28.3 years (10,337 days).
Specimen TCGA-DX-AB3B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c56ae4dc-8bfd-4557-b91c-5ba5139847ca.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB3B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b08d74ca-278e-4536-a2e8-312d462cf4af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,961; copy number 1: 4,009; copy number 2: 53,248; copy number 3: 55; copy number 4: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB3B-01A-11D-A416-01): tumor purity 0.73, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:164,213,539–164,322,223, 2 genes: PRPS1P1, CYP2C56P.
- chr2:210,002,565–210,233,976, 7 genes (within-gene range 0–2): RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:30,516,266–30,557,174, 2 genes: LINC02569, GNL1.
- chr8:17,596,312–17,596,378, 1 gene: AP006248.1.
- chr11:75,742,129–75,768,647, 2 genes: RN7SL786P, AP001922.1.
- chr13:68,693,804–68,694,081, 1 gene: RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,009. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
